Somatic mutation profile of tumor specimen TCGA-FX-A3RE-01A (aliquot TCGA-FX-A3RE-01A-11D-A228-09) from TCGA case TCGA-FX-A3RE, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 65.0 years (23,757 days).
Specimen TCGA-FX-A3RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bde292a-cb0a-44ce-8574-014ca7134ebb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FX-A3RE-10A (Blood Derived Normal), aliquot TCGA-FX-A3RE-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bf8009b-6ed1-4177-8681-ac03cd323aaf

The open-access MAF lists 117 somatic variants for this specimen: 88 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 25, Nonsense Mutation 4, Splice Site 2, 3'UTR 2, Frame Shift Del 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.6356C>T p.A2119V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.784); catalogued as COSV100719427; called by muse, mutect2, varscan2
- ADGRG7 | c.629A>G p.Q210R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99841566; called by muse, mutect2
- ADGRV1 | c.4865A>G p.Y1622C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1450234666; called by muse, mutect2, varscan2
- ANK3 | c.2429C>T p.S810L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1219017706; called by muse, mutect2, varscan2
- CEMIP2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs780849860; called by muse, mutect2, varscan2
- CPSF1 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782361727, COSV58234136; called by muse, mutect2, varscan2
- CSF1R | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1315261761, COSV53835903; called by muse, mutect2, varscan2
- CTNND2 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58894961; called by muse, mutect2, varscan2
- CTSE | c.703G>A p.E235K (on ENST00000360218; = p.E230K on NM_001910.4) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs781829575, COSV100733511; called by muse, mutect2, varscan2
- DNAH8 | c.1385A>G p.Q462R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV100547258; called by muse, mutect2, varscan2
- DOCK6 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1412788055; called by muse, mutect2, varscan2
- GASK1B | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV56704196; called by muse, mutect2
- GRIPAP1 | c.2185-1G>A p.X729_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99502148; called by muse, mutect2, varscan2
- KCNA1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1352539698, COSV66836946; called by muse, mutect2, varscan2
- KCNK3 | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as rs1211206106; called by muse, mutect2
- KDM3B | c.3803C>T p.P1268L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs763718862; called by muse, mutect2, varscan2
- LRP2 | c.5098+1G>T p.X1700_splice | Splice Site (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99790307; called by muse, mutect2, varscan2
- MUC7 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.148); catalogued as COSV59217543; called by muse, mutect2, varscan2
- NBR1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs769242413; called by muse, mutect2
- PCDHB4 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52022782; called by muse, mutect2, varscan2
- PHF3 | c.4535A>G p.N1512S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV50328753; called by muse, mutect2, varscan2
- RBBP7 | c.520G>C p.G174R | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66300588; called by muse, mutect2
- SLC1A3 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99468296; called by muse, mutect2
- SPHKAP | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.796); catalogued as rs749080877; called by muse, mutect2, varscan2
- SYMPK | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.422); catalogued as rs1263705470; called by muse, mutect2, varscan2
- TNPO1 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.096); catalogued as COSV100474038; called by muse, mutect2, varscan2
- WFS1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.048); catalogued as rs765260306; called by muse, mutect2, varscan2
- XIRP2 | c.1423G>T p.D475Y (on ENST00000628543; = p.D650Y on NM_152381.6) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54737175; called by muse, varscan2
- ZIK1 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV56737626; called by muse, mutect2
- ZMAT1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV65659724; called by muse, mutect2, varscan2
- AGTR2 | c.307T>A p.Y103N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APOB | c.11335T>C p.F3779L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ARAP2 | c.2069A>G p.K690R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARFGEF1 | c.1608A>C p.E536D | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASAP1 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- BIRC6 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- BOD1L1 | c.6347A>T p.E2116V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- C5 | c.4669A>T p.I1557F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CACNA1G | c.6599C>A p.P2200Q | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC185 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CLDN1 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CNGA3 | c.2039G>C p.G680A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX60 | c.376T>C p.C126R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DPY19L4 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DYTN | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EML5 | c.862A>T p.S288C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GABRR1 | c.1122G>C p.R374S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- GDI1 | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- GLE1 | c.1458A>G p.K486= | Splice Region (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- GPC4 | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HERC2 | c.12047G>A p.R4016K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); called by muse, mutect2
- HTT | c.8752G>C p.A2918P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INF2 | c.2513C>G p.S838* | Nonsense Mutation (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- IRS1 | c.2917G>C p.A973P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM4B | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 4/104 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KHDC4 | c.383A>T p.E128V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- KRT76 | c.1319T>A p.L440H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC17 | c.1132T>G p.C378G | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MAN1A1 | c.1701G>T p.W567C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR3 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.19568C>A p.P6523Q | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MYBBP1A | c.2235G>C p.E745D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYH1 | c.3265T>A p.F1089I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MYH2 | c.999_1004delinsCAGGA p.M333Ifs*27 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2*
- NDST4 | c.1589T>A p.L530* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- NFIB | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NPAS3 | c.871C>T p.R291W (on ENST00000356141 / NM_001164749.2; = p.R259W on NM_022123.3) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NPBWR2 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- P2RX2 | c.687C>G p.H229Q (on ENST00000343948 / NM_170683.4; = p.H157Q on NM_012226.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PCLO | c.11729A>T p.E3910V | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PHACTR2 | c.1647G>A p.M549I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- PITPNM3 | c.2299G>T p.V767F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRH | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- RBM22 | c.147del p.R50Gfs*28 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- RIOK2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SCN9A | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERINC4 | c.1135T>A p.F379I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SPOCD1 | c.3050A>T p.K1017M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TC2N | c.262A>G p.R88G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TCHH | c.5421G>T p.R1807S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- TENM1 | c.6136T>A p.F2046I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- TENM1 | c.1600A>T p.T534S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TFAP2A | c.987T>A p.D329E (on ENST00000482890; = p.D321E on NM_001032280.3) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.298); called by muse, mutect2
- TMEM98 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TUBGCP3 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- USP6 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- WIPF1 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- XIRP2 | c.1415C>T p.A472V (on ENST00000628543; = p.A647V on NM_152381.6) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, varscan2
- ADCY2 | c.3105A>C p.G1035= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- BANK1 | c.885A>T p.S295= | Silent (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- C3AR1 | c.894T>C p.P298= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- CHST12 | c.768C>A p.R256= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- CPXCR1 | c.738T>C p.S246= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs749565646; called by muse, mutect2, varscan2
- CRAT | c.1044G>A p.G348= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs374221134, COSV58876252; called by muse, mutect2, varscan2
- CRB1 | c.2772G>A p.E924= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- FAM135B | c.2010A>T p.S670= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- FAM71F1 | c.339C>A p.L113= | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- ITGA2B | c.855C>T p.V285= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs1156847555; called by muse, mutect2, varscan2
- KLK3 | c.468C>A p.G156= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- MUS81 | c.1509C>T p.L503= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV57261652; called by muse, mutect2, varscan2
- NINL | c.2664G>A p.T888= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs377035866; called by muse, mutect2, varscan2
- P2RX3 | c.918C>T p.D306= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs750733213; called by muse, mutect2, varscan2
- PRX | c.4206C>A p.P1402= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52519093; called by mutect2, varscan2
- PSG4 | c.225C>G p.L75= | Silent (SNP) | VAF 63/162 reads (39%) | catalogued as rs758975074; called by muse, mutect2, varscan2
- SASH1 | c.3546G>T p.V1182= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- SERPINB3 | c.147T>G p.T49= | Silent (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.934C>T p.L312= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- SMYD4 | c.2196C>G p.R732= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- SP140 | c.1653G>A p.K551= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- STK11IP | c.1611C>G p.L537= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- UNC13C | c.4044G>A p.V1348= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- WDFY2 | c.306C>T p.N102= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- ZNF416 | c.1218A>G p.T406= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs754031914; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506173 del CTTTG | RNA (DEL) | VAF 29/71 reads (41%) | catalogued as rs1250718881; called by pindel, varscan2
- CXCL9 | c.*1G>C | 3'UTR (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99345850; called by muse, mutect2, varscan2
- H2AB1 | c.*1C>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100371839; called by mutect2, varscan2
- TMEM99 | n.679T>C | RNA (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
